Somatic mutation profile of tumor specimen C3L-00970-03 (aliquot CPT0102240009) from CPTAC case C3L-00970, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 55.3 years (20,187 days).
Specimen C3L-00970-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b73a4c21-7cf9-4059-9f4c-aa826f9e800f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00970-31 (Blood Derived Normal), aliquot CPT0101030002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d74f9f6a-d615-4de1-94b8-728880e73897

The open-access MAF lists 78 somatic variants for this specimen: 56 protein-altering or splice-affecting, 13 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 13, Intron 5, Frame Shift Del 3, RNA 3, Splice Region 2, Splice Site 2, Nonsense Mutation 2, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPZ | c.1864C>T p.R622C (on ENST00000360986 / NM_001014447.3; = p.R611C on NM_003652.3) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs770337063, COSV59925820; called by mutect2, varscan2
- CTNS | c.88C>A p.P30T | Missense Mutation (SNP) | VAF 105/554 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV50439999; called by muse, mutect2, varscan2
- DHX16 | c.1918C>T p.R640W | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs143108219; called by muse, mutect2, varscan2
- DOP1B | c.2941G>A p.G981S | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.78); catalogued as rs767212028, COSV67693782; called by muse, mutect2, varscan2
- GDF10 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199534890; called by muse, mutect2, varscan2
- KCNH7 | c.2963A>G p.D988G | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.03); catalogued as rs1280195613; called by muse, mutect2
- KIF3B | c.535C>G p.L179V | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1281015769; called by muse, mutect2, varscan2
- LTBP2 | c.1902C>G p.D634E | Missense Mutation (SNP) | VAF 51/397 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV56209731; called by muse, mutect2, varscan2
- MEGF11 | c.2384T>C p.L795P | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV56547777; called by muse, mutect2, varscan2
- MPHOSPH10 | c.832G>T p.D278Y | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV54907109; called by muse, varscan2
- MSR1 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs761676407, COSV100026809; called by muse, mutect2, varscan2
- NEDD1 | c.1975C>T p.H659Y | Missense Mutation (SNP) | VAF 61/284 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as rs1464423880; called by muse, mutect2, varscan2
- OR52J3 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs200293164, COSV66746279; called by muse, mutect2, varscan2
- OR5L2 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.097); catalogued as rs144590289; called by muse, mutect2, varscan2
- PTPRN2 | c.2244G>T p.E748D | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV67064757; called by muse, mutect2, varscan2
- TPO | c.2515G>A p.V839I | Missense Mutation (SNP) | VAF 90/357 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs146351101, CM024371; called by muse, mutect2, varscan2
- TTN | c.31003C>T p.P10335S (on ENST00000591111; = p.P9408S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/177 reads (14%) | PolyPhen probably damaging (0.998); catalogued as COSV60024222; called by muse, mutect2, varscan2
- VHL | c.491del p.Q164Rfs*6 | Frame Shift Del (DEL) | VAF 109/424 reads (26%) | catalogued as CM951296, COSV56546711, COSV56549758, COSV56554584; called by mutect2, pindel, varscan2
- ADGRD2 | c.929C>A p.P310H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- C1orf146 | c.330-1G>T p.X110_splice | Splice Site (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- CANT1 | c.518T>A p.F173Y | Missense Mutation (SNP) | VAF 100/545 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- CROT | c.1019A>G p.Y340C | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- DCAF17 | c.1132C>T p.H378Y | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- DNAH8 | c.10362G>T p.Q3454H | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EEF1AKMT2 | c.408C>G p.D136E | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- EVA1B | c.68-3C>A | Splice Region (SNP) | VAF 52/211 reads (25%) | called by muse, mutect2, varscan2
- GRIPAP1 | c.851A>T p.E284V | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRM8 | c.453A>G p.I151M | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- ITGB4 | c.2061A>T p.E687D | Missense Mutation (SNP) | VAF 69/302 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- KDM5C | c.2244-1G>A p.X748_splice | Splice Site (SNP) | VAF 123/260 reads (47%) | called by muse, mutect2, varscan2
- KLHDC3 | c.62C>A p.A21D | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2
- MAP3K7 | c.633_637del p.V212Qfs*17 | Frame Shift Del (DEL) | VAF 29/122 reads (24%) | called by mutect2, pindel, varscan2
- METAP1D | c.539C>A p.T180K | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MUC16 | c.8060C>G p.T2687S | Missense Mutation (SNP) | VAF 18/249 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); called by muse, mutect2
- MYCN | c.896T>C p.I299T | Missense Mutation (SNP) | VAF 61/252 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- N4BP1 | c.613A>G p.I205V | Missense Mutation (SNP) | VAF 67/259 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NBEAL2 | c.3893C>G p.T1298R | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NDUFA12 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 101/418 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PEG3 | c.4258G>T p.G1420* | Nonsense Mutation (SNP) | VAF 43/230 reads (19%) | called by muse, mutect2, varscan2
- PLA2G4C | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- PROM1 | c.1504G>T p.V502F | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PSMD11 | c.862A>G p.K288E | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- RAD21 | c.440A>T p.E147V | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RIMS2 | c.4088G>T p.S1363I (on ENST00000666250 / NM_001348490.2; = p.S934I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SIRT1 | c.2235C>G p.N745K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLC22A5 | c.1125C>G p.N375K | Missense Mutation (SNP) | VAF 167/594 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC3A2 | c.364A>C p.K122Q | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SLC46A2 | c.1409G>A p.G470E | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMARCA4 | c.2699A>T p.H900L | Missense Mutation (SNP) | VAF 36/344 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- SPEN | c.3231_3233delinsA p.S1078Kfs*16 | Frame Shift Del (DEL) | VAF 9/97 reads (9%) | called by pindel, varscan2*
- SREK1 | c.607A>G p.S203G | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.225); called by muse, varscan2
- TRIM15 | c.1081G>A p.G361S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- UTRN | c.1729A>T p.K577* | Nonsense Mutation (SNP) | VAF 28/143 reads (20%) | called by muse, mutect2, varscan2
- WNT8A | c.619_621del p.Y207del | In Frame Del (DEL) | VAF 102/376 reads (27%) | called by mutect2, pindel, varscan2
- ZFP69B | c.342A>G p.G114= | Splice Region (SNP) | VAF 34/343 reads (10%) | called by muse, mutect2
- ZNF536 | c.2446C>A p.P816T | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BCL9L | c.1359G>A p.Q453= | Silent (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- BIRC3 | c.483C>T p.S161= | Silent (SNP) | VAF 56/202 reads (28%) | catalogued as rs781540627; called by muse, mutect2, varscan2
- BTN2A2 | c.1053G>A p.R351= | Silent (SNP) | VAF 25/190 reads (13%) | catalogued as rs772088652; called by muse, mutect2, varscan2
- CLDN15 | c.441C>T p.F147= | Silent (SNP) | VAF 47/260 reads (18%) | catalogued as COSV57659652; called by muse, mutect2, varscan2
- DCUN1D2 | c.165C>A p.S55= | Silent (SNP) | VAF 48/243 reads (20%) | called by muse, mutect2, varscan2
- DPEP3 | c.432C>T p.V144= | Silent (SNP) | VAF 29/154 reads (19%) | catalogued as COSV52051697; called by muse, mutect2, varscan2
- FNDC7 | c.1938C>A p.I646= | Silent (SNP) | VAF 43/154 reads (28%) | catalogued as rs748095829, COSV54757615; called by muse, mutect2, varscan2
- KIAA1549L | c.105G>A p.E35= (on ENST00000321505; = p.E332= on NM_012194.3) | Silent (SNP) | VAF 34/219 reads (16%) | catalogued as COSV99683761; called by muse, mutect2, varscan2
- LARP1 | c.2529C>G p.P843= (on ENST00000518297 / NM_033551.3; = p.P766= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 36/196 reads (18%) | called by muse, mutect2, varscan2
- RUSC2 | c.4320C>T p.H1440= | Silent (SNP) | VAF 39/167 reads (23%) | called by muse, mutect2, varscan2
- SLC6A15 | c.376C>A p.R126= | Silent (SNP) | VAF 24/171 reads (14%) | catalogued as COSV57019577, COSV57021155; called by muse, varscan2
- TRIM36 | c.1029A>G p.L343= | Silent (SNP) | VAF 46/244 reads (19%) | catalogued as rs1461090890; called by muse, mutect2, varscan2
- TRIM65 | c.774T>C p.P258= | Silent (SNP) | VAF 24/146 reads (16%) | called by muse, mutect2, varscan2
- AC092118.1 | n.970C>A | RNA (SNP) | VAF 66/330 reads (20%) | called by mutect2, varscan2
- AC135782.1 | n.307C>T | RNA (SNP) | VAF 25/94 reads (27%) | catalogued as rs540434801; called by muse, mutect2, varscan2
- PADI2 | c.-34del | 5'UTR (DEL) | VAF 7/82 reads (9%) | called by mutect2, pindel
- RNF207 | c.324+76C>A | Intron (SNP) | VAF 39/145 reads (27%) | called by muse, mutect2, varscan2
- RPSAP52 | n.825T>G | RNA (SNP) | VAF 31/183 reads (17%) | called by muse, mutect2, varscan2
- SOD2 | c.226+29A>G | Intron (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- UBE2H | c.53+3496_53+3522del | Intron (DEL) | VAF 20/148 reads (14%) | called by mutect2, pindel
- VNN2 | c.538-779C>G | Intron (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2, varscan2
- ZNF497 | c.-111-984A>G | Intron (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2
